Somatic mutation profile of tumor specimen 0DU3LK from CCDI case PBCKMA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 3.4 years (1,245 days).
Specimen 0DU3LK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 673d342d-a160-4207-beb2-e14a299fa05c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b2aa5ae-8a9b-497e-99a4-dbfd734645cc

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Nonsense Mutation 1, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 382/627 reads (61%) | hotspot (GDC flag); catalogued as COSV61375361; called by muse, varscan2
- ANKRD52 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 268/1324 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1296018775; called by muse, varscan2
- DTNB | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 536/1988 reads (27%) | catalogued as rs770240065, COSV56482808; called by muse, varscan2
- NOVA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 342/1558 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs547813363; called by muse, varscan2
- OR6B3 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 267/2407 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs765260499, COSV100097645; called by muse, varscan2
- PIK3CA | c.2946G>T p.E982D | Missense Mutation (SNP) | VAF 206/729 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV55883412; called by muse, varscan2
- TTN | c.13237C>G p.R4413G (on ENST00000591111; = p.R4367G on NM_003319.4) | Missense Mutation (SNP) | VAF 758/3237 reads (23%) | PolyPhen benign (0.011); called by muse, varscan2
- UNC13C | c.2258A>G p.Q753R | Missense Mutation (SNP) | VAF 308/998 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, varscan2
- SORCS1 | c.2727G>A p.A909= | Silent (SNP) | VAF 314/1034 reads (30%) | catalogued as rs747274447, COSV53887422; called by muse, varscan2
- RPL37A | c.132+30_132+34del | Intron (DEL) | VAF 166/1124 reads (15%) | called by pindel, varscan2
- TRIM5 | c.896-26T>C | Intron (SNP) | VAF 272/629 reads (43%) | called by muse, varscan2
- ZNF567 | c.136+64A>T | Intron (SNP) | VAF 264/816 reads (32%) | called by muse, varscan2
